Gene-level copy-number profile of tumor specimen TCGA-BR-A452-01A from TCGA case TCGA-BR-A452, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.8 years (21,107 days).
Specimen TCGA-BR-A452-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.88de11e5-1fc3-4ae9-9a22-a9f0df63d6f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A452-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7d42d8a9-8eeb-4428-a232-c6b884a24178

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 202; copy number 2: 10,532; copy number 3: 8,858; copy number 4: 30,798; copy number 5: 4,006; copy number 6: 2,103; copy number 7: 2,920; copy number 8: 351; copy number 9: 19; copy number 10: 7; copy number 11: 17; copy number 13: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A452-01A-91D-A253-01): tumor purity 0.62, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:950,849–1,367,613, 1 gene (within-gene range 0–2): SNTG2.
- chr2:1,158,310–1,346,568, 2 genes: AC114808.2, AC108462.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 46 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,735,479–228,858,556, 3 genes, copy number 13: RHOU, AL078624.2, AL078624.1.
- chr1:234,724,042–235,328,219, 17 genes, copy number 11 (within-gene range 7–11): LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23.
- chr6:106,629,578–106,975,627, 7 genes, copy number 10: QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24.
- chr8:127,072,694–127,742,951, 12 genes, copy number 9: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr16:78,793,584–79,004,730, 7 genes, copy number 9 (within-gene range 2–9): AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2.

Autosomal genes at a single copy (total copy number 1): 202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
